Somatic mutation profile of tumor specimen MMRF_1876_1_BM_CD138pos (aliquot MMRF_1876_1_BM_CD138pos_T1_KBS5U_L05557) from MMRF case MMRF_1876, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 70.1 years (25,611 days).
Specimen MMRF_1876_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2cb9b467-3385-4932-bcff-3eb4c9b396a7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1876_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1876_1_PB_Whole_C3_KBS5U_L05579; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/537f08c8-eef4-435d-8ecf-464075392459

The open-access MAF lists 180 somatic variants for this specimen: 67 protein-altering or splice-affecting, 25 silent, 88 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, 3'UTR 53, Silent 25, Intron 21, 5'UTR 8, Frame Shift Ins 3, 3'Flank 3, Splice Site 3, Nonsense Mutation 2, 5'Flank 2, Frame Shift Del 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 59/202 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- BBS9 | c.44G>A p.G15E | Missense Mutation (SNP) | VAF 78/427 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs1436396518; called by muse, mutect2, varscan2
- CYP2C9 | c.1247G>C p.G416A | Missense Mutation (SNP) | VAF 27/191 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as COSV53251899; called by muse, mutect2, varscan2
- DIS3 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750002908; called by muse, mutect2, varscan2
- FAM114A2 | c.993+1G>A p.X331_splice | Splice Site (SNP) | VAF 30/87 reads (34%) | catalogued as rs750941972; called by muse, mutect2, varscan2
- FREM2 | c.6098C>T p.T2033M | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as rs143791655; called by muse, mutect2, varscan2
- GCH1 | c.358G>T p.A120S | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as CM148084; called by muse, mutect2, varscan2
- GRIN3A | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 45/112 reads (40%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.014); catalogued as COSV100701717; called by muse, mutect2, varscan2
- IGLV3-1 | c.245G>A p.G82D | Missense Mutation (SNP) | VAF 136/139 reads (98%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); catalogued as rs373575867; called by muse, varscan2
- LILRA4 | c.790C>T p.P264S | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.124); catalogued as COSV52492379; called by muse, mutect2
- MUC16 | c.20731del p.T6911Pfs*39 | Frame Shift Del (DEL) | VAF 42/203 reads (21%) | catalogued as rs1184538119, COSV67488631; called by mutect2, pindel, varscan2
- MYO5B | c.5362C>T p.R1788W | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53210653; called by muse, mutect2
- NUB1 | c.1118G>A p.R373Q | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.014); catalogued as rs373576077; called by muse, mutect2, varscan2
- OR6K2 | c.509C>A p.S170* | Nonsense Mutation (SNP) | VAF 40/205 reads (20%) | catalogued as COSV62743313, COSV62743319; called by muse, mutect2, varscan2
- PAOX | c.1519C>T p.P507S | Missense Mutation (SNP) | VAF 41/164 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs1305996057; called by muse, mutect2, varscan2
- PCNX4 | c.316A>C p.T106P | Missense Mutation (SNP) | VAF 60/199 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs961637421; called by muse, mutect2, varscan2
- RBM46 | c.445C>T p.P149S | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV55976890; called by muse, mutect2, varscan2
- RFPL3 | c.584G>A p.G195E (on ENST00000249007 / NM_001098535.1; = p.G166E on NM_006604.2) | Missense Mutation (SNP) | VAF 95/306 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1242975851; called by muse, mutect2, varscan2
- SCN4A | c.2419G>A p.A807T | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.018); catalogued as rs770694096, COSV71127802; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- SDHAP2 | n.1435+1G>A | Splice Site (SNP) | VAF 38/132 reads (29%) | catalogued as rs775505324; called by muse, varscan2
- TAS2R50 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 61/217 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.381); catalogued as rs745998395; called by muse, mutect2, varscan2
- TBX21 | c.660C>G p.Y220* | Nonsense Mutation (SNP) | VAF 19/80 reads (24%) | catalogued as COSV51596442; called by muse, mutect2, varscan2
- TECTA | c.3329C>T p.T1110I | Missense Mutation (SNP) | VAF 25/226 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as rs560247815; called by muse, mutect2, varscan2
- TFE3 | c.1413G>T p.R471S | Missense Mutation (SNP) | VAF 38/59 reads (64%) | SIFT tolerated (0.54); PolyPhen benign (0.042); catalogued as COSV100252475; called by muse, mutect2, varscan2
- TRIM3 | c.82C>T p.R28W | Missense Mutation (SNP) | VAF 147/241 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs551613146, COSV61983653; called by muse, mutect2, varscan2
- WEE1 | c.1660C>T p.P554S | Missense Mutation (SNP) | VAF 31/264 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.712); catalogued as rs771907098; called by muse, varscan2
- ZNF350 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 54/77 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV54708609; called by muse, mutect2, varscan2
- ACADL | c.557C>T p.T186I | Missense Mutation (SNP) | VAF 28/45 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ACSBG2 | c.424G>C p.E142Q | Missense Mutation (SNP) | VAF 61/196 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); called by muse, mutect2, varscan2
- AP5B1 | c.1880T>G p.L627W | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGEF17 | c.2291G>A p.S764N | Missense Mutation (SNP) | VAF 52/135 reads (39%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP1A4 | c.22G>C p.G8R | Missense Mutation (SNP) | VAF 44/212 reads (21%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); called by muse, varscan2
- CACNA2D4 | c.2356C>A p.P786T | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- CAGE1 | c.760G>T p.V254F (on ENST00000512086; = p.V118F on NM_205864.3) | Missense Mutation (SNP) | VAF 18/238 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); called by muse, mutect2
- CHST13 | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.86); called by muse, mutect2
- DIP2C | c.3032C>A p.A1011D | Missense Mutation (SNP) | VAF 76/143 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ELAVL3 | c.378C>A p.N126K | Missense Mutation (SNP) | VAF 20/173 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- FAM114A2 | c.467C>G p.S156C | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAT3 | c.512C>T p.T171I | Missense Mutation (SNP) | VAF 28/628 reads (4%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.944); called by muse, mutect2
- FGD1 | c.2863C>G p.P955A | Missense Mutation (SNP) | VAF 40/43 reads (93%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- GCNT4 | c.689A>G p.D230G | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GNA12 | c.934A>C p.K312Q | Missense Mutation (SNP) | VAF 17/240 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.007); called by muse, mutect2
- GPSM1 | c.457G>A p.G153R | Missense Mutation (SNP) | VAF 66/193 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GRAMD2A | c.368T>C p.I123T | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.34); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HIVEP3 | c.4042G>A p.G1348S | Missense Mutation (SNP) | VAF 65/211 reads (31%) | SIFT tolerated (0.94); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- IGLV3-1 | c.276_277insCA p.I93Qfs*? | Frame Shift Ins (INS) | VAF 28/131 reads (21%) | called by pindel, varscan2
- KNG1 | c.1880C>T p.P627L | Missense Mutation (SNP) | VAF 89/423 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- LRP1B | c.3482dup p.D1162Gfs*4 | Frame Shift Ins (INS) | VAF 45/120 reads (38%) | called by mutect2, pindel, varscan2
- MORF4L1 | c.1040C>A p.A347D (on ENST00000331268 / NM_206839.2; = p.A308D on NM_006791.4) | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- MRPL37 | c.1066G>C p.V356L | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- MUC17 | c.12403+1G>A p.X4135_splice | Splice Site (SNP) | VAF 16/402 reads (4%) | called by muse, mutect2
- MYH8 | c.3946G>A p.E1316K | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MYO1A | c.1752C>A p.N584K | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MYO5C | c.2565G>T p.E855D | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NLRC5 | c.4357del p.L1453Ffs*6 | Frame Shift Del (DEL) | VAF 28/106 reads (26%) | called by mutect2, pindel, varscan2
- OGG1 | c.788A>C p.Q263P | Missense Mutation (SNP) | VAF 10/153 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.89); called by muse, mutect2
- OR4D10 | c.153T>G p.C51W | Missense Mutation (SNP) | VAF 41/341 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PCDHA1 | c.567T>G p.S189R | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.099); called by muse, mutect2
- PSMB1 | c.141T>A p.D47E | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PSMD14 | c.382A>T p.N128Y | Missense Mutation (SNP) | VAF 65/154 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- RANBP2 | c.3506G>A p.G1169D | Missense Mutation (SNP) | VAF 22/242 reads (9%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.999); called by muse, mutect2
- SH3BP5 | c.602T>C p.L201P | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SIPA1L2 | c.1980G>A p.K660= | Splice Region (SNP) | VAF 8/98 reads (8%) | called by muse, mutect2
- TENT5C | c.78dup p.E27* | Frame Shift Ins (INS) | VAF 66/251 reads (26%) | called by mutect2, pindel, varscan2
- TEX44 | c.136T>A p.W46R | Missense Mutation (SNP) | VAF 25/170 reads (15%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- TNF | c.695C>A p.A232D | Missense Mutation (SNP) | VAF 11/322 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2
- ZC3H12C | c.625G>A p.D209N | Missense Mutation (SNP) | VAF 52/274 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ADAMTSL3 | c.981A>G p.K327= | Silent (SNP) | VAF 34/161 reads (21%) | called by muse, mutect2, varscan2
- BEND4 | c.1164G>A p.L388= | Silent (SNP) | VAF 80/152 reads (53%) | catalogued as COSV72469008; called by muse, mutect2, varscan2
- BICRA | c.2325G>A p.S775= | Silent (SNP) | VAF 30/101 reads (30%) | catalogued as rs1389984593, COSV101194282; called by muse, mutect2, varscan2
- CAD | c.1461G>A p.E487= | Silent (SNP) | VAF 67/133 reads (50%) | called by muse, mutect2, varscan2
- CDH8 | c.843T>C p.Y281= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as rs1270673041; called by muse, mutect2, varscan2
- CHODL | c.297C>T p.F99= | Silent (SNP) | VAF 34/208 reads (16%) | catalogued as rs753371867; called by muse, mutect2, varscan2
- CSHL1 | c.336G>T p.L112= (on ENST00000309894 / NM_022581.3; = p.L18= on NM_001318.4) | Silent (SNP) | VAF 24/66 reads (36%) | called by muse, mutect2, varscan2
- DDIAS | c.754C>T p.L252= | Silent (SNP) | VAF 26/887 reads (3%) | catalogued as rs1340902611; called by muse, mutect2
- EEF1AKMT3 | c.231G>A p.K77= | Silent (SNP) | VAF 12/196 reads (6%) | called by muse, mutect2
- FIGN | c.549G>A p.Q183= | Silent (SNP) | VAF 7/80 reads (9%) | called by muse, mutect2
- FLNC | c.7188C>A p.P2396= | Silent (SNP) | VAF 40/211 reads (19%) | called by muse, mutect2, varscan2
- GNAT2 | c.795C>A p.V265= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as COSV100655934; called by muse, mutect2, varscan2
- HCN1 | c.726A>C p.G242= | Silent (SNP) | VAF 40/110 reads (36%) | catalogued as rs199622227; ClinVar: likely benign; called by muse, mutect2, varscan2
- IGLL5 | c.81G>T p.L27= | Silent (SNP) | VAF 61/63 reads (97%) | catalogued as rs56055217, COSV73249379; called by muse, mutect2, varscan2
- MAP2K4 | c.483T>C p.I161= | Silent (SNP) | VAF 46/143 reads (32%) | catalogued as COSV100796121; called by muse, mutect2, varscan2
- NCOA6 | c.5685C>T p.G1895= | Silent (SNP) | VAF 14/149 reads (9%) | catalogued as rs764791597; called by muse, mutect2
- OBSCN | c.20859C>T p.G6953= | Silent (SNP) | VAF 104/323 reads (32%) | called by muse, mutect2, varscan2
- PCDHGB2 | c.1659C>T p.G553= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as rs1326854162, COSV53961610; called by muse, mutect2, varscan2
- POLR2C | c.717G>A p.L239= | Silent (SNP) | VAF 62/123 reads (50%) | catalogued as COSV99538511; called by muse, mutect2, varscan2
- PREP | c.1839C>T p.G613= (on ENST00000369110; = p.G679= on NM_002726.5) | Silent (SNP) | VAF 26/57 reads (46%) | called by muse, mutect2, varscan2
- SOCS3 | c.219C>T p.S73= | Silent (SNP) | VAF 55/109 reads (50%) | catalogued as rs566417772; called by muse, mutect2, varscan2
- SPHKAP | c.2919C>T p.N973= | Silent (SNP) | VAF 70/159 reads (44%) | catalogued as rs369849755; called by muse, mutect2, varscan2
- TNPO1 | c.720G>A p.R240= | Silent (SNP) | VAF 5/84 reads (6%) | called by muse, mutect2
- VWC2L | c.165T>C p.D55= | Silent (SNP) | VAF 76/143 reads (53%) | called by muse, mutect2, varscan2
- ZBTB48 | c.1800C>T p.H600= | Silent (SNP) | VAF 23/212 reads (11%) | catalogued as rs748441279; called by muse, mutect2, varscan2
- ABCF3 | c.*64T>C | 3'UTR (SNP) | VAF 38/102 reads (37%) | called by muse, mutect2, varscan2
- ABI2 | c.*11338G>T | 3'UTR (SNP) | VAF 28/82 reads (34%) | called by muse, mutect2, varscan2
- ACY1 | c.1002-58T>C | Intron (SNP) | VAF 26/102 reads (25%) | called by muse, mutect2, varscan2
- ALDH6A1 | c.*3559G>A | 3'UTR (SNP) | VAF 37/321 reads (12%) | called by muse, mutect2, varscan2
- AMBRA1 | c.*139A>G | 3'UTR (SNP) | VAF 7/150 reads (5%) | called by muse, mutect2
- ANHX | c.*456C>T | 3'UTR (SNP) | VAF 55/144 reads (38%) | called by muse, mutect2, varscan2
- ANKRA2 | c.514+64T>C | Intron (SNP) | VAF 3/18 reads (17%) | called by muse, mutect2
- ARHGAP26 | c.*4974G>A | 3'UTR (SNP) | VAF 15/90 reads (17%) | called by muse, mutect2, varscan2
- ASIC2 | c.556-180286C>G | Intron (SNP) | VAF 6/28 reads (21%) | called by muse, mutect2
- BCL7A | chr12:122021492 C>T | 5'Flank (SNP) | VAF 36/86 reads (42%) | catalogued as COSV55846308, COSV55846472; called by muse, mutect2, varscan2
- BMP6 | c.*782_*801del | 3'UTR (DEL) | VAF 22/102 reads (22%) | called by mutect2, pindel, varscan2
- C10orf67 | c.*820_*822dup | 3'UTR (INS) | VAF 22/50 reads (44%) | called by mutect2, pindel, varscan2
- CALM1 | c.*561G>T | 3'UTR (SNP) | VAF 27/105 reads (26%) | called by muse, mutect2, varscan2
- CAMK1D | c.299+51T>A | Intron (SNP) | VAF 34/112 reads (30%) | called by muse, mutect2, varscan2
- CCDC170 | c.*373C>T | 3'UTR (SNP) | VAF 15/63 reads (24%) | catalogued as rs1461763581; called by muse, mutect2, varscan2
- CDH23 | c.1449+23G>A | Intron (SNP) | VAF 27/62 reads (44%) | called by muse, mutect2, varscan2
- COL18A1 | c.*851C>A | 3'UTR (SNP) | VAF 62/186 reads (33%) | called by muse, mutect2, varscan2
- CYP20A1 | c.*224T>G | 3'UTR (SNP) | VAF 18/89 reads (20%) | called by muse, mutect2, varscan2
- CYP2F1 | c.964+28A>T | Intron (SNP) | VAF 46/62 reads (74%) | called by muse, mutect2, varscan2
- DEFB118 | c.*254C>A | 3'UTR (SNP) | VAF 25/60 reads (42%) | called by muse, mutect2, varscan2
- EPB41L3 | c.2158-35C>T | Intron (SNP) | VAF 17/81 reads (21%) | catalogued as rs770909034; called by muse, mutect2, varscan2
- ERC1 | c.*5260T>C | 3'UTR (SNP) | VAF 18/285 reads (6%) | called by muse, mutect2
- FLT4 | c.*183C>A | 3'UTR (SNP) | VAF 14/61 reads (23%) | called by muse, mutect2, varscan2
- FO681492.1 | c.-298C>T | 5'UTR (SNP) | VAF 18/119 reads (15%) | called by mutect2, varscan2
- FZD3 | c.*9602A>G | 3'UTR (SNP) | VAF 48/68 reads (71%) | called by muse, mutect2, varscan2
- GCSAML | c.*1042C>A | 3'UTR (SNP) | VAF 62/250 reads (25%) | called by muse, mutect2, varscan2
- GNRHR2P1 | n.222C>T | RNA (SNP) | VAF 4/148 reads (3%) | called by muse, mutect2
- GPR26 | c.*3874A>T | 3'UTR (SNP) | VAF 17/46 reads (37%) | called by muse, mutect2, varscan2
- H2AC11 | c.*862_*865del | 3'UTR (DEL) | VAF 20/68 reads (29%) | catalogued as rs1316489690; called by mutect2, varscan2
- HELZ2 | c.1731-45T>C | Intron (SNP) | VAF 23/81 reads (28%) | called by muse, mutect2, varscan2
- HMCN1 | c.-260C>A | 5'UTR (SNP) | VAF 12/54 reads (22%) | called by muse, mutect2
- HOXB9 | c.*1195C>T | 3'UTR (SNP) | VAF 28/80 reads (35%) | called by muse, mutect2, varscan2
- HSPA4 | c.*787T>C | 3'UTR (SNP) | VAF 6/100 reads (6%) | called by muse, mutect2
- IGSF5 | c.*692T>C | 3'UTR (SNP) | VAF 20/112 reads (18%) | called by muse, mutect2, varscan2
- IKZF4 | c.716-29T>A | Intron (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2
- INHBA | c.*466G>A | 3'UTR (SNP) | VAF 45/73 reads (62%) | called by muse, mutect2, varscan2
- INSYN2A | c.*706C>G | 3'UTR (SNP) | VAF 25/85 reads (29%) | called by muse, mutect2, varscan2
- ITCH | chr20:34510623 A>T | 3'Flank (SNP) | VAF 30/52 reads (58%) | called by muse, mutect2, varscan2
- KLHL7 | c.-233C>T | 5'UTR (SNP) | VAF 23/57 reads (40%) | catalogued as rs1003166937; called by muse, mutect2, varscan2
- LAIR1 | c.416-1509T>A | Intron (SNP) | VAF 18/94 reads (19%) | called by muse, mutect2, varscan2
- LNX1 | c.*1096A>T | 3'UTR (SNP) | VAF 22/67 reads (33%) | called by muse, mutect2, varscan2
- LRRC2 | chr3:46518043 A>T | 3'Flank (SNP) | VAF 44/206 reads (21%) | called by muse, mutect2, varscan2
- MYCN | c.-176del | 5'UTR (DEL) | VAF 15/63 reads (24%) | catalogued as rs1200941109; called by mutect2, pindel, varscan2
- NDST3 | c.*250G>C | 3'UTR (SNP) | VAF 17/67 reads (25%) | called by muse, mutect2, varscan2
- NTNG2 | c.*2260G>A | 3'UTR (SNP) | VAF 8/28 reads (29%) | called by muse, varscan2
- NTRK3 | c.*5541A>C | 3'UTR (SNP) | VAF 19/96 reads (20%) | called by muse, mutect2, varscan2
- ONECUT2 | c.*4366A>T | 3'UTR (SNP) | VAF 61/212 reads (29%) | called by muse, mutect2, varscan2
- PAX8 | c.*1513G>C | 3'UTR (SNP) | VAF 13/122 reads (11%) | called by muse, mutect2, varscan2
- PHLDA1 | c.-616G>T | 5'UTR (SNP) | VAF 51/111 reads (46%) | called by muse, mutect2, varscan2
- PLCXD1 | c.*327C>T | 3'UTR (SNP) | VAF 3/12 reads (25%) | called by muse, mutect2
- PRPSAP1 | c.-167C>A | 5'UTR (SNP) | VAF 27/66 reads (41%) | catalogued as rs926413885; called by muse, mutect2, varscan2
- PRTG | c.397+1883G>T | Intron (SNP) | VAF 28/514 reads (5%) | called by muse, mutect2
- PYGO1 | c.*4213G>C | 3'UTR (SNP) | VAF 24/127 reads (19%) | called by muse, mutect2, varscan2
- RAPGEF1 | c.*2067C>A | 3'UTR (SNP) | VAF 42/93 reads (45%) | called by muse, mutect2, varscan2
- RBFOX1 | c.351+152231G>A | Intron (SNP) | VAF 12/37 reads (32%) | called by muse, mutect2, varscan2
- RIPOR2 | c.*1919A>C | 3'UTR (SNP) | VAF 21/109 reads (19%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159749 G>A | 5'Flank (SNP) | VAF 8/25 reads (32%) | called by muse, varscan2
- RSF1 | c.*427A>G | 3'UTR (SNP) | VAF 48/126 reads (38%) | catalogued as rs1049040864; called by muse, mutect2, varscan2
- RTF1 | c.1818+28C>T | Intron (SNP) | VAF 43/191 reads (23%) | called by muse, mutect2, varscan2
- SCN1A | c.*2004G>A | 3'UTR (SNP) | VAF 6/48 reads (13%) | catalogued as rs1418887290; called by muse, mutect2, varscan2
- SCUBE1 | c.844+964C>A | Intron (SNP) | VAF 9/125 reads (7%) | called by muse, mutect2
- SDK1 | c.5828-5859C>T | Intron (SNP) | VAF 12/98 reads (12%) | catalogued as rs1267210708; called by muse, mutect2, varscan2
- SEMA3A | c.*1648A>T | 3'UTR (SNP) | VAF 41/99 reads (41%) | called by muse, mutect2, varscan2
- SEMA5A | c.*6469C>T | 3'UTR (SNP) | VAF 37/66 reads (56%) | called by muse, mutect2, varscan2
- SHH | c.*1524G>T | 3'UTR (SNP) | VAF 28/145 reads (19%) | catalogued as rs1422544425; called by muse, mutect2, varscan2
- SIGLEC6 | c.*413G>A | 3'UTR (SNP) | VAF 10/130 reads (8%) | catalogued as rs886385278; called by muse, mutect2
- SLC12A1 | c.*771A>G | 3'UTR (SNP) | VAF 13/170 reads (8%) | called by muse, mutect2
- SLC35A4 | c.-68T>A | 5'UTR (SNP) | VAF 38/333 reads (11%) | called by muse, mutect2, varscan2
- SLC35D3 | c.*197T>C | 3'UTR (SNP) | VAF 21/64 reads (33%) | called by muse, mutect2, varscan2
- SLITRK4 | chrX:143625831 T>A | 3'Flank (SNP) | VAF 33/35 reads (94%) | catalogued as rs1181868867; called by muse, mutect2, varscan2
- SNX27 | c.*3092T>A | 3'UTR (SNP) | VAF 14/129 reads (11%) | called by muse, mutect2, varscan2
- SPTLC2 | c.*3860T>C | 3'UTR (SNP) | VAF 7/78 reads (9%) | called by muse, mutect2
- ST6GAL2 | c.*3131C>T | 3'UTR (SNP) | VAF 10/49 reads (20%) | called by muse, mutect2, varscan2
- TCF7L2 | c.552+49327C>T | Intron (SNP) | VAF 9/60 reads (15%) | catalogued as rs780446801, COSV60503859; called by muse, mutect2, varscan2
- TENM3 | c.*2599A>G | 3'UTR (SNP) | VAF 32/60 reads (53%) | called by muse, mutect2, varscan2
- TMEM179 | c.*2128A>T | 3'UTR (SNP) | VAF 14/70 reads (20%) | called by muse, mutect2, varscan2
- TMEM95 | c.*128G>C | 3'UTR (SNP) | VAF 87/352 reads (25%) | called by muse, mutect2, varscan2
- TNIK | c.*2202T>G | 3'UTR (SNP) | VAF 35/171 reads (20%) | called by muse, mutect2, varscan2
- TNS1 | c.*1921G>T | 3'UTR (SNP) | VAF 17/52 reads (33%) | called by muse, mutect2, varscan2
- TOR1B | c.*482G>A | 3'UTR (SNP) | VAF 13/75 reads (17%) | called by muse, mutect2, varscan2
- TRIM46 | c.*534C>G | 3'UTR (SNP) | VAF 48/241 reads (20%) | called by muse, mutect2, varscan2
- TULP4 | c.*4770T>G | 3'UTR (SNP) | VAF 34/71 reads (48%) | called by muse, mutect2, varscan2
- UBE2F | c.214+8621G>A | Intron (SNP) | VAF 36/104 reads (35%) | called by muse, mutect2, varscan2
- VPS13A | c.6378+887T>C | Intron (SNP) | VAF 13/117 reads (11%) | called by muse, mutect2, varscan2
- VXN | c.440+147G>C | Intron (SNP) | VAF 19/74 reads (26%) | called by muse, mutect2, varscan2
- ZFP28 | c.898+236A>G | Intron (SNP) | VAF 6/44 reads (14%) | called by muse, mutect2, varscan2
- ZNF211 | c.91-568G>C | Intron (SNP) | VAF 5/58 reads (9%) | called by muse, mutect2
- ZNF92 | c.-59T>A | 5'UTR (SNP) | VAF 72/114 reads (63%) | called by muse, mutect2, varscan2
